Somatic mutation profile of tumor specimen 0DPZTL from CCDI case PBCECS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 4.6 years (1,666 days).
Specimen 0DPZTL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00695596-6b0b-4f52-ad57-1c44732eba8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPZUD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa593113-7d83-49db-a19d-452a3fc15018

The open-access MAF lists 41 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 10, Intron 8, Frame Shift Del 1, Splice Region 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.730A>C p.T244P | Missense Mutation (SNP) | VAF 188/743 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs397507465, CM072907; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR4 | c.1605C>A p.N535K | Missense Mutation (SNP) | VAF 164/498 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519792, COSV52800481, COSV52801581; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.4270G>C p.E1424Q (on ENST00000506720 / NM_001322402.2; = p.E1313Q on NM_015236.6) | Missense Mutation (SNP) | VAF 196/574 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.655); catalogued as COSV72231150; called by muse, mutect2, varscan2
- CCDC141 | c.3520del p.E1174Kfs*8 | Frame Shift Del (DEL) | VAF 164/780 reads (21%) | catalogued as COSV55374265; called by mutect2, varscan2
- FLG | c.3595A>G p.T1199A | Missense Mutation (SNP) | VAF 147/418 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1425893947; called by muse, mutect2, varscan2
- KIF26B | c.769T>C p.Y257H | Missense Mutation (SNP) | VAF 140/397 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV101313741; called by muse, mutect2, varscan2
- NEK7 | c.596C>G p.T199R | Missense Mutation (SNP) | VAF 176/589 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66314751, COSV66315611; called by muse, mutect2, varscan2
- RNF14 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 214/658 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs781535864, COSV61662290; called by muse, mutect2, varscan2
- ARHGEF37 | c.1465-3C>A | Splice Region (SNP) | VAF 137/440 reads (31%) | called by muse, mutect2
- CUL5 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 291/1515 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- E2F5 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 261/1769 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ESAM | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 205/983 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBN3 | c.4895G>T p.C1632F | Missense Mutation (SNP) | VAF 159/726 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FLG | c.3938A>G p.Q1313R | Missense Mutation (SNP) | VAF 142/403 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GRIP2 | c.1992G>C p.E664D (on ENST00000619221; = p.E567D on NM_001080423.4) | Missense Mutation (SNP) | VAF 190/588 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OOSP2 | c.170G>T p.C57F | Missense Mutation (SNP) | VAF 57/1341 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR2K2 | c.97G>T p.E33* (on ENST00000374428; = p.E4* on NM_205859.2) | Nonsense Mutation (SNP) | VAF 144/331 reads (44%) | called by muse, mutect2, varscan2
- OR52E6 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 186/1018 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, varscan2
- SCN1A | c.1872G>T p.Q624H | Missense Mutation (SNP) | VAF 265/1180 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SGK1 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 238/740 reads (32%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOAT2 | c.1035G>T p.L345F | Missense Mutation (SNP) | VAF 190/697 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TATDN3 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 407/1175 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ERVMER34-1 | c.156T>C p.N52= | Silent (SNP) | VAF 311/778 reads (40%) | called by muse, mutect2, varscan2
- GRK2 | c.732G>T p.S244= | Silent (SNP) | VAF 51/823 reads (6%) | catalogued as COSV57951757; called by muse, mutect2
- HEATR5A | c.5664T>C p.Y1888= | Silent (SNP) | VAF 253/1049 reads (24%) | called by muse, mutect2, varscan2
- ICE2 | c.2160G>A p.S720= | Silent (SNP) | VAF 39/404 reads (10%) | catalogued as rs778477425; called by muse, mutect2
- LYG1 | c.210C>A p.P70= | Silent (SNP) | VAF 319/1185 reads (27%) | called by muse, mutect2, varscan2
- MYO15A | c.8409C>G p.V2803= | Silent (SNP) | VAF 195/585 reads (33%) | called by muse, mutect2, varscan2
- OR2C3 | c.660C>T p.G220= | Silent (SNP) | VAF 196/541 reads (36%) | catalogued as rs769258016; called by muse, mutect2, varscan2
- RB1CC1 | c.3258G>A p.K1086= | Silent (SNP) | VAF 274/1537 reads (18%) | called by muse, mutect2, varscan2
- WT1 | c.1458C>A p.R486= | Silent (SNP) | VAF 472/1168 reads (40%) | called by muse, mutect2, varscan2
- ZNF579 | c.33C>A p.G11= | Silent (SNP) | VAF 38/776 reads (5%) | called by muse, mutect2
- CCNL1 | c.488+94G>C | Intron (SNP) | VAF 64/301 reads (21%) | called by muse, mutect2, varscan2
- CFAP70 | c.1855-75C>T | Intron (SNP) | VAF 82/303 reads (27%) | catalogued as rs1373560174, COSV100160606; called by muse, mutect2, varscan2
- CHMP4A | c.359+25G>C | Intron (SNP) | VAF 83/340 reads (24%) | called by muse, mutect2, varscan2
- COL6A2 | c.2461+2369C>T | Intron (SNP) | VAF 121/388 reads (31%) | catalogued as rs532760001; called by muse, mutect2, varscan2
- CTNNB1 | c.2137+20C>G | Intron (SNP) | VAF 160/476 reads (34%) | called by muse, mutect2, varscan2
- NRG1 | c.503-5966A>T | Intron (SNP) | VAF 184/1115 reads (17%) | catalogued as COSV99828506; called by muse, varscan2
- PNKD | c.236+1175G>T | Intron (SNP) | VAF 164/677 reads (24%) | called by muse, mutect2, varscan2
- RELN | c.*25C>A | 3'UTR (SNP) | VAF 141/656 reads (21%) | called by mutect2, varscan2
- ZNF107 | c.-204-1860T>A | Intron (SNP) | VAF 45/174 reads (26%) | called by muse, mutect2, varscan2
